Surgical pathology report (de-identified scan), TCGA case TCGA-ZF-AA4U, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Sheffield, specimen TCGA-ZF-AA4U-01A (Primary Tumor).

Histopathology Histopathology

CHF ICD-O-3
Carcinoma, urothelial NOS 8120/3
path
Carcinoma, transitional cell NOS 8120/3
Site: Bladder NOS C67.9
Op 4/30/14

Specimen Comments
SPECIMEN

1. Bladder and prostate
2. Internal iliac lymph node left

CLINICAL DETAILS

Invasive bladder carcinoma.

MACROSCOPY

1. Bladder and prostate measuring 95mm SI, 130mm AP and 130mm ML. The bladder contains extensive papillary tumour occupying the entire circumference of the lower half. On slicing there is probable invasion of the bladder neck and possibly the prostate. There is no visible involvement of the extravescicle fat.
2. Piece of fibrofatty tissue 23 x 8 x 5mm containing a single 7mm lymph node.

MICROSCOPY

1. Sections of the macroscopically visible exophytic tumour confirm a papillary and solid poorly differentiated transitional cell carcinoma, with a better differentiated exophytic component, and invading the lamina propria and the muscularis propria to reach the perivesicle fat. There is possible lymphovascular invasion. There is no lymphocytic infiltrate of the tumour host interface. No glandular or squamoid differentiation is noted. There is no neuroendocrine differentiation.

The tumour extends into both lobes of the prostate but involves the lower lobe on the right side and there is tumour in the periprostatic soft tissue of the left lower lobe.

Both ureteric margins are morphologically normal except for dilatation of the lumen on the left side. There is no evidence of dysplasia or carcinoma in situ. The prostatic urethra also shows no evidence of dysplasia or carcinoma in situ. The tumour extends to within 5mm of the right circumferential surgical resection margin and 4mm of the left circumferential surgical resection margin. Random sections taken from the background bladder show another G2pTa transitional cell carcinoma and the background shows focal carcinoma in situ.

2. All the tissue was processed and there is no nodal tissue. There is no evidence of metastatic carcinoma.

SUMMARY (Parts 1 and 2)

Bladder and prostate; The appearances are those of a transitional cell carcinoma of the bladder (G3) invading the prostate. Surgical resection margins are clear (G3 pT4a pNx pMx).

Ref:

Pathologists -

Source: NCI Genomic Data Commons file cde612fb-c49a-450f-8778-c4be79e436b9 (TCGA-ZF-AA4U.72EA5495-3D5D-4547-B2BE-54C138294216.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).